Gene-level copy-number profile of tumor specimen TCGA-AL-3468-01A from TCGA case TCGA-AL-3468, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 74.5 years (27,205 days).
Specimen TCGA-AL-3468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.3c560c12-27b2-45a1-96e2-fbc93547e124.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AL-3468-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files).
https://portal.gdc.cancer.gov/files/ecf24295-b439-4edd-a54f-735d26a60856

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,166; copy number 2: 37,926; copy number 3: 15,714; copy number 4: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AL-3468-01): tumor purity 0.89, ploidy 2.35, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
